Surgical pathology report (de-identified scan), TCGA case TCGA-CR-6487, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-6487-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) TONGUE, INFERIOR VALLECULAR MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY.
- 2) TONGUE, MIDLINE BASE MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY.
- 3) TONGUE, INFERIOR DEEP LEFT LYMPHOID BASE, EXCISION: NEGATIVE FOR MALIGNANCY.
- 4) TONGUE, LATERAL POSTERIOR MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY.
- 5) TONGUE, ANTERIOR LATERAL MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY.
- 6) TONSIL/BASE OF TONGUE, LEFT, EXCISION: FRAGMENTS OF MODERATELY TO POORLY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA, AT LEAST 1.9 CM IN GREATEST DIMENSION (SEE COMMENT).

COMMENT: As the tumor was submitted in a fragmented fashion, it is difficult to ascertain the exact size of the lesion. Thus, these findings correspond to at least an AJCC [REDACTED] edition pathologic stage I (pT1pN n/a pM n/a).

Upper Aerodigestive Tract-including Minor Salivary Glands, Lip, Oral cavity, Nasal Cavity, Paranasal Sinuses, Oropharynx, Nasopharynx, and Hypopharynx

Summary of Findings:

Specimen Type: excision

Tumor Site: tonsil/base of tongue

Tumor Size: at least 1.9 cm

Laterality:

Right

X Left

Bilateral

Midline

Not specified

Margins (select all that apply)

Cannot be assessed

[page 2 of 3]
☒ Margin uninvolved by invasive carcinoma
(Specify distance to closest margins); at least 2mm from midline base
margin
Margin involved by invasive carcinoma
Margins uninvolved by carcinoma in situ
(Specify distance to closest margins)
Margins involved by carcinoma in situ

Not applicable

Histologic Type: squamous cell carcinoma

Histologic Grade: moderate to poorly

Pathologic Staging (pTMN) I

Primary tumor (pT): pT1

Regional Lymph Nodes (pN): pN n/a

Number examined: 0

Numbered involved: 0

Extracapsular extension: n/a

Perineural invasion: (Select one)pM n/a

Yes

☒ No

Not evaluable

Bony/Cartilage Invasion: (Select one)

Yes

No

☒ Not evaluable

Lymph-Vascular invasion: (Select one)

Yes

☒ No

Not evaluable

HPV testing ordered: Yes (performed on oral cavity and oropharyngeal
squamous cell carcinomas)

**Electronically Signed Out by

[REDACTED]

CLINICAL DATA

Clinical Diagnosis: Malignant neoplasm oropharynx

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Left tonsil-base of tongue squamous cell
mass

Tissue Submitted: 1)inferior vallecular margin; 2)midline
base of tongue margin; 3)inferior deep
left lymphoid base of tongue; 4)lateral
posterior margin; 5)anterior lateral

[page 3 of 3]
margin; 6)left tonsil and base of tongue
margin

GROSS DESCRIPTION:

1) SOURCE: Inferior Vallecular Margin

Received fresh, labeled "inferior vallecular margin" is a single fragment of soft pink-tan tissue, which measures 1.8 x 0.5 x 0.3 cm. The tissue is entirely submitted.

Summary of sections: 1A, 1/1.

2) SOURCE: Midline Base of Tongue Margin

Received fresh, labeled "midline base of tongue margin" is a single fragment of pink-tan soft tissue, which measures 1.8 x 0.3 x 0.3 cm. The tissue is entirely submitted.

Summary of sections: 2A, 1/1.

3) SOURCE: Inferior Deep Left Lymphoid Base of Tongue

Received fresh, labeled "inferior deep left lymphoid base of tongue" is a single fragment of pink-tan soft tissue, which measures 1.1 x 0.4 x 0.3 cm. The tissue is entirely submitted.

Summary of sections: 3A, 1/1.

4) SOURCE: Lateral Posterior Margin

Received fresh, labeled "lateral posterior margin" is a 1.3 x 1.0 x 0.4 cm fragment of soft pink-tan tissue. The tissue is entirely submitted.

Summary of sections: 4A, 1/1.

5) SOURCE: Anterior Lateral Margin

Received fresh, labeled "anterior lateral margin" is a 2.0 x 0.5 x 0.3 cm fragment of soft pink-tan tissue. The tissue is entirely submitted.

Summary of sections: 5A, 1/1.

6) SOURCE: Left Tonsil/Base of Tongue Margin

Received fresh, labeled "left tonsil and base of tongue mass" are several disarticulated, hemorrhagic fragments of pink-tan soft tissue, which measure 8.5 x 4.0 x 0.8 cm in aggregate. The tissue is entirely submitted.

Summary of sections: 6A-6I, M/1.

Dictated by

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 06cae540-31be-48af-81d4-687741e2a3e1 (TCGA-CR-6487.15757009-261B-4C96-842A-0543FB8A4F94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).